Surgical pathology report (de-identified scan), TCGA case TCGA-A3-3343, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-A3-3343-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

DIAGNOSIS

DIAGNOSIS:

A. Mesenteric nodule:

Benign, fat necrosis, fibrosis, mild chronic inflammation.

B. Left nephrectomy:

Carcinoma.

Tumor Characteristics:

1. Histologic type: Conventional (clear cell) renal cell carcinoma
2. Tumor site: Mid pole
3. Tumor size: Approximately 8 cm. in greatest dimension.
- Macroscopic extent of tumor: Tumor limited to kidney
4. Nuclear grade: Fuhrman grade 3/4
5. Lympho-vascular space invasion: Yes
6. Transcapsular invasion: No
7. Renal vein invasion: No
8. Vena caval invasion: Not resected
9. Adrenal gland: Not resected

Surgical Margin Status:

1. Soft tissue margins: Negative
2. Ureteral margin: Negative
3. Vascular margins: Negative

Lymph Node Status: (refer to diagnosis C below)

1. Total number of lymph nodes examined: 1
2. Number of lymph nodes containing metastatic carcinoma: List nodal sites: None

Other Significant Findings:

Mild chronic pyelonephritis is present.

Stage: T2, N0, M0

C. Paraaortic lymph node:

Benign, hyperplasia.

Electronic Signature:

CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis: Renal mass - left.

Postoperative Diagnosis: Same

Symptoms/Radiologic Findings:

SPECIMENS:

- A. Mesenteric nodule.
- B. Left kidney.
- C. Paraaortic lymph nodes.

SPECIMEN DATA

[page 2 of 2]
GROSS DESCRIPTION:

A. Received in a single container labeled [REDACTED] mesenteric nodule and consists of a gray-tan nodule with attached fibroadipose tissue measuring 1.5 x 0.5 x 0.5 cm. The specimen is bisected, the nodule has a white-tan fibrotic cut surface. Within the center there is a cavity containing red-brown material. The specimen is sectioned and is entirely submitted in a single cassette labeled [REDACTED].

B. Received in a single container labeled [REDACTED] left kidney and consists of a kidney with attached perinephric fat that measures 15 x 14 x 7 cm. and weighs 640 grams. There is no adrenal gland attached. The ureter measures 5 cm. in length and 0.3 cm. diameter and is grossly unremarkable. The renal vein stump measures 1 cm. in length and 0.3 cm. in diameter and is grossly unremarkable. The renal artery stump measures 1.7 cm. in length and 0.5 cm. in diameter and is grossly unremarkable. The kidney has been bisected and reveals a large circumscribed golden yellow slightly lobulated mass that measures 8 cm. in greatest dimension that is predominantly within the mid pole lesion that is beneath the capsular surface. There is no gross invasion into the surrounding perinephric fat. The surrounding renal cortex is brown to red-tan and measures 0.7 cm. in thickness and shows a well demarcated adrenal cortex appearance. Received with the specimen are two cassettes one green, one yellow labeled [REDACTED].

Representative sections are submitted in cassettes labeled [REDACTED] follows: sections from mass in blocks 1 through 5; ureter in block 6; renal artery and vein in block 7; uninvolved kidney in block 8.

C. Received in a single container labeled [REDACTED] paraaortic lymph node and consists of a piece of yellow-tan fibroadipose tissue measuring 2.5 x 1.5 x 0.5 cm. On sectioning there reveals a single lymph node measuring 1 x 0.5 x 0.3 cm. The lymph node is bisected, the cut surface is pale tan. The lymph node is entirely submitted in a single cassette labeled [REDACTED].

Source: NCI Genomic Data Commons file daed7fb8-2579-44b1-811d-1daa72bae649 (TCGA-A3-3343.2400724A-CB14-49FE-889A-E044A80B27C8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).